Somatic mutation profile of tumor specimen TCGA-CG-5732-01A (aliquot TCGA-CG-5732-01A-11D-1600-08) from TCGA case TCGA-CG-5732, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 66.7 years (24,379 days).
Specimen TCGA-CG-5732-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4c7f213-be60-4de6-b02f-dfec2bd34582.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5732-11A (Solid Tissue Normal), aliquot TCGA-CG-5732-11A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0114567-eceb-4a26-b4e7-a5106a38df6a

The open-access MAF lists 57 somatic variants for this specimen: 38 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 16, Nonsense Mutation 2, Intron 1, Splice Region 1, Frame Shift Ins 1, RNA 1, Splice Site 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CUX2 | c.4224G>T p.M1408I | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV55629076; called by muse, mutect2
- DPF1 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV62792537; called by muse, mutect2, varscan2
- ERN2 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374029883, COSV55621449, COSV55624602; called by muse, mutect2, varscan2
- FBN1 | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57314054; called by muse, mutect2
- FBXO47 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs149066313; called by muse, mutect2, varscan2
- FBXW11 | c.793T>C p.W265R | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51608280; called by muse, mutect2, varscan2
- FLG | c.7286G>A p.G2429E | Missense Mutation (SNP) | VAF 160/596 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.125); catalogued as rs1169103537, COSV64240076; called by muse, mutect2, varscan2
- FLG | c.6199C>A p.P2067T | Missense Mutation (SNP) | VAF 61/685 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.042); catalogued as COSV64236246, COSV64240081; called by muse, mutect2
- FSHR | c.212A>G p.D71G | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.536); catalogued as COSV58621367; called by muse, mutect2
- GLUD2 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.06); catalogued as COSV60151708; called by muse, mutect2, varscan2
- HEPH | c.2725G>T p.E909* (on ENST00000343002; = p.E642* on NM_014799.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV57961694; called by muse, mutect2
- KDM4D | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs781973111, COSV58634249; called by muse, mutect2
- LRP1B | c.7790G>A p.R2597H | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs968042014, COSV67204592; called by muse, mutect2, varscan2
- NAALADL2 | c.2187T>C p.Y729= | Splice Region (SNP) | VAF 6/26 reads (23%) | catalogued as COSV71984308; called by muse, mutect2, varscan2
- NR3C1 | c.1418G>T p.C473F | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51541858; called by muse, mutect2, varscan2
- NT5C2 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as rs774448444, COSV58415584; called by muse, mutect2, varscan2
- PDZRN4 | c.2486A>T p.Y829F (on ENST00000402685 / NM_001164595.2; = p.Y571F on NM_013377.4) | Missense Mutation (SNP) | VAF 28/325 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV54197771; called by muse, mutect2
- PINX1 | c.614C>T p.T205M | Missense Mutation (SNP) | VAF 22/395 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as rs374613074; called by muse, mutect2
- PNPLA7 | c.475A>C p.K159Q | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52997292; called by muse, mutect2
- PPL | c.4172G>A p.R1391Q | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs573477337, COSV52167327; called by muse, mutect2, varscan2
- PTPRZ1 | c.283A>C p.I95L | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV66434580; called by muse, mutect2
- SAP30L | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV51737351; called by muse, mutect2, varscan2
- SCN9A | c.5603T>G p.M1868R (on ENST00000303354; = p.M1857R on NM_002977.3) | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV57606159; called by muse, mutect2
- SEPTIN6 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 149/356 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.99); catalogued as rs1398546784, COSV59713416; called by muse, mutect2, varscan2
- SERPINB8 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 89/288 reads (31%) | catalogued as COSV54639180, COSV54639409; called by muse, mutect2, varscan2
- SLC15A2 | c.1549G>A p.V517M | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs372532662; called by muse, mutect2, varscan2
- SP110 | c.916C>T p.H306Y | Missense Mutation (SNP) | VAF 100/378 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.206); catalogued as rs148304482; called by muse, mutect2, varscan2
- TCERG1L | c.1049C>T p.T350M | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs563448537, COSV64048159, COSV64048909; called by muse, mutect2, varscan2
- TDRD1 | c.966G>C p.K322N | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1345127223, COSV52589544; called by muse, mutect2
- TESPA1 | c.944T>G p.V315G (on ENST00000316577 / NM_001098815.3; = p.V177G on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57256990; called by muse, mutect2, varscan2
- TRPS1 | c.3123T>G p.S1041R (on ENST00000220888 / NM_001330599.2; = p.S1054R on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV55234597; called by muse, mutect2
- TSHZ2 | c.2063C>A p.A688D | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV61587975; called by muse, mutect2
- TTBK2 | c.1410-2A>G p.X470_splice | Splice Site (SNP) | VAF 30/96 reads (31%) | catalogued as COSV51158893; called by muse, mutect2
- TTC3 | c.3577G>C p.E1193Q | Missense Mutation (SNP) | VAF 23/239 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV61288757, COSV61297998; called by muse, mutect2
- TTLL5 | c.2459C>A p.T820N | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as COSV54031233; called by muse, mutect2, varscan2
- YME1L1 | c.2272G>C p.A758P (on ENST00000326799 / NM_139312.3; = p.A701P on NM_014263.4) | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as COSV58758925; called by muse, mutect2, varscan2
- SPINK5 | c.859dup p.T287Nfs*2 | Frame Shift Ins (INS) | VAF 21/94 reads (22%) | called by mutect2, pindel, varscan2
- TP53 | c.686_687del p.C229Yfs*10 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- ACKR1 | c.87C>A p.S29= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as COSV63672500; called by muse, mutect2, varscan2
- ASMT | c.297G>A p.P99= | Silent (SNP) | VAF 70/204 reads (34%) | catalogued as rs770973782, COSV67109759; called by muse, mutect2, varscan2
- CACNA2D3 | c.2991C>G p.S997= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as rs1405033579, COSV55528963; called by muse, mutect2, varscan2
- CRHBP | c.285C>T p.I95= | Silent (SNP) | VAF 28/179 reads (16%) | catalogued as COSV57188099; called by muse, mutect2, varscan2
- CSMD3 | c.9720T>C p.S3240= (on ENST00000297405 / NM_001363185.1; = p.S3071= on NM_052900.3) | Silent (SNP) | VAF 6/155 reads (4%) | catalogued as COSV52149677; called by muse, mutect2
- CWF19L2 | c.1098T>C p.A366= | Silent (SNP) | VAF 35/173 reads (20%) | catalogued as COSV56511160; called by muse, mutect2, varscan2
- DLK1 | c.30C>T p.V10= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV57991219; called by muse, mutect2
- EPB41L4A | c.420G>A p.A140= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as rs746775281, COSV54863525; called by muse, mutect2, varscan2
- KIAA1614 | c.606G>A p.L202= | Silent (SNP) | VAF 55/195 reads (28%) | catalogued as rs368044144; called by muse, mutect2, varscan2
- KRIT1 | c.684T>C p.C228= | Silent (SNP) | VAF 18/214 reads (8%) | catalogued as COSV60667500; called by muse, mutect2
- MAGI2 | c.1071C>T p.I357= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as rs754843992, COSV62637309; called by muse, mutect2, varscan2
- MSH5 | c.2199G>A p.E733= | Silent (SNP) | VAF 40/511 reads (8%) | catalogued as COSV65172938; called by muse, mutect2
- PDHA2 | c.531G>A p.L177= | Silent (SNP) | VAF 13/117 reads (11%) | catalogued as COSV54778435; called by muse, mutect2, varscan2
- PTPRD | c.1161G>A p.S387= | Silent (SNP) | VAF 45/254 reads (18%) | catalogued as rs779673772, COSV61938007; called by muse, mutect2, varscan2
- TIAM1 | c.1440C>T p.D480= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs745535556, COSV54545301; called by muse, mutect2, varscan2
- TTN | c.1953C>T p.A651= (on ENST00000591111; = p.A605= on NM_003319.4) | Silent (SNP) | VAF 52/173 reads (30%) | catalogued as rs778742098, COSV59983791; ClinVar: likely benign; called by muse, mutect2, varscan2
- AL590867.2 | n.221A>T | RNA (SNP) | VAF 64/362 reads (18%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-10668dup | Intron (INS) | VAF 49/200 reads (25%) | called by mutect2, pindel, varscan2
- UBE2V1 | chr20:50115494 G>T | 5'Flank (SNP) | VAF 16/170 reads (9%) | catalogued as COSV100441701; called by muse, mutect2
